Somatic mutation profile of tumor specimen C3L-07953-05 (aliquot CPT0513070006) from CPTAC case C3L-07953, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 83.0 years (30,333 days).
Specimen C3L-07953-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce7dbd30-92e6-4224-b339-4076fd1550c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07953-31 (Blood Derived Normal), aliquot CPT0513180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d2e016-19cd-45ff-a0cd-125db096316e

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 19, Splice Site 1, Splice Region 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 24/252 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- HRH3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890686938, COSV58050367; called by muse, mutect2, varscan2
- HSD11B2 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 26/431 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1139495, COSV99340979; called by muse, mutect2
- KCNG1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 25/741 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV65368950; called by muse, mutect2
- NCR1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 31/615 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs763296705; called by muse, mutect2
- PADI3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 16/379 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs146396025; called by muse, mutect2
- PRUNE1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV54846893; called by muse, mutect2
- RGPD4 | c.4559T>C p.V1520A | Missense Mutation (SNP) | VAF 5/304 reads (2%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs888333375; called by muse, mutect2
- SNX21 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 28/619 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1302708117; called by muse, mutect2
- SVEP1 | c.6385G>A p.G2129S | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52840021, COSV99928352; called by muse, mutect2
- TENM1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs374613583, COSV64425363; called by muse, mutect2, varscan2
- TTC29 | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1324766671; called by muse, mutect2
- TTN | c.25705G>A p.G8569S (on ENST00000591111; = p.G7642S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/270 reads (10%) | PolyPhen benign (0.021); catalogued as rs72648991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF831 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 57/559 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs768443242, COSV64043342; called by muse, varscan2
- ABHD12B | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- ADGRF5 | c.330C>T p.V110= | Splice Region (SNP) | VAF 10/185 reads (5%) | called by muse, mutect2
- C10orf105 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 29/623 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.352); called by muse, mutect2
- CDCA3 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.117); called by muse, mutect2
- CDK11B | c.1865G>C p.W622S | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- CENPC | c.1990A>T p.N664Y | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- CFAP47 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DOCK2 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- DROSHA | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); called by muse, mutect2
- DYRK1B | c.1597T>G p.S533A | Missense Mutation (SNP) | VAF 19/609 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); called by muse, mutect2
- IGDCC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/252 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- LAMA5 | c.8407A>G p.K2803E | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2
- LRIT2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- MALRD1 | c.3454A>T p.S1152C | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NGLY1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- PCDH12 | c.2390A>T p.D797V | Missense Mutation (SNP) | VAF 30/439 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- PEG3 | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- PLEKHN1 | c.946-1G>A p.X316_splice (on ENST00000379409; = p.X264_splice on NM_032129.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/368 reads (7%) | called by muse, mutect2
- SDK2 | c.3305A>G p.N1102S | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.129); called by muse, mutect2
- TYRO3 | c.2285A>T p.Y762F | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKR1C2 | c.948T>C p.N316= | Silent (SNP) | VAF 12/260 reads (5%) | catalogued as COSV66334724; called by muse, mutect2
- ANK2 | c.11523G>A p.P3841= | Silent (SNP) | VAF 27/438 reads (6%) | catalogued as rs143290935; called by muse, mutect2
- C1RL | c.237G>C p.V79= | Silent (SNP) | VAF 18/527 reads (3%) | called by muse, mutect2
- CCSAP | c.513A>G p.Q171= | Silent (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- FITM2 | c.342C>T p.I114= | Silent (SNP) | VAF 23/486 reads (5%) | catalogued as rs556654904; called by muse, mutect2
- KCNJ14 | c.114G>A p.P38= | Silent (SNP) | VAF 63/439 reads (14%) | catalogued as rs776822495; called by muse, mutect2, varscan2
- LRRC38 | c.531G>A p.A177= | Silent (SNP) | VAF 42/594 reads (7%) | catalogued as rs571180670; called by muse, mutect2
- NBEAL1 | c.5205G>A p.K1735= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- NRXN2 | c.360C>T p.D120= | Silent (SNP) | VAF 34/544 reads (6%) | catalogued as rs1391089296; called by muse, mutect2
- PCDHA12 | c.1683C>T p.N561= | Silent (SNP) | VAF 50/709 reads (7%) | catalogued as COSV56525703; called by muse, mutect2
- PFAS | c.120G>A p.L40= | Silent (SNP) | VAF 39/289 reads (13%) | catalogued as rs1363379224; called by muse, mutect2, varscan2
- PLXNA4 | c.492C>T p.N164= | Silent (SNP) | VAF 34/413 reads (8%) | catalogued as rs755930438, COSV58130365; called by muse, mutect2
- PRRT1 | c.807G>A p.R269= | Silent (SNP) | VAF 43/805 reads (5%) | catalogued as rs767375357; called by muse, mutect2
- RNH1 | c.1170C>T p.L390= | Silent (SNP) | VAF 28/554 reads (5%) | catalogued as rs760790035; called by muse, mutect2
- RTN4RL1 | c.1107C>T p.G369= | Silent (SNP) | VAF 50/481 reads (10%) | catalogued as rs770578456; called by muse, varscan2
- SLC66A1 | c.240C>T p.G80= | Silent (SNP) | VAF 25/375 reads (7%) | catalogued as rs537651536; called by muse, mutect2
- TESK2 | c.1272C>T p.I424= | Silent (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- TRABD2A | c.831T>A p.I277= (on ENST00000409520 / NM_001277053.2; = p.I228= on NM_001080824.3) | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- TTN | c.19929T>G p.T6643= (on ENST00000591111; = p.T5716= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- AC004837.1 | n.87C>A | RNA (SNP) | VAF 37/750 reads (5%) | called by muse, mutect2
